Surgical pathology report (de-identified scan), TCGA case TCGA-CV-5977, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-5977-01A (Primary Tumor).

[page 1 of 3]
DIAGNOSIS

- (A) LEFT NECK, LEVEL I:
METASTATIC SQUAMOUS CARCINOMA IN ONE OF TWELVE LYMPH NODES (1/12).
Extracapsular extension is not identified.
- (B) LEFT NECK DISSECTION, LEVEL II:
METASTATIC SQUAMOUS CARCINOMA IN ONE OF TEN LYMPH NODES (1/10).
Extracapsular extension is not identified.
- (C) LEFT NECK DISSECTION, LEVEL III:
METASTATIC SQUAMOUS CARCINOMA IN ONE OF TWELVE LYMPH NODES (1/12).
Extracapsular extension is not identified.
- (D) LEFT NECK DISSECTION, LEVEL IV:
Thirteen lymph nodes, no tumor present (0/13).
- (E) RIGHT NECK DISSECTION, LEVEL I:
Three lymph nodes, no tumor present (0/3).
Salivary gland, no tumor present
- (F) RIGHT NECK DISSECTION, LEVEL II:
Twelve lymph nodes, no tumor present (0/12).
Salivary gland, no tumor present
- (G) RIGHT NECK DISSECTION, LEVEL III:
Seventeen lymph nodes, no tumor present (0/7).
- (H) PARTIAL GLOSSECTOMY:
INVASIVE SQUAMOUS CARCINOMA -- Moderately differentiated
Tumor Features:
Gross: Ulcerating
Size: 4.5 cm in largest dimension
Invasion: Present, depth at least 1.0 cm (measured on slide)
Tumor Border: Infiltrative with thick cords > 4 cells
Perineural Invasion: Present, Moderate
Vascular Invasion: Present
Lymphocyte Infiltration: Moderate
Mucosal Margin: (en-face) Negative for invasive carcinoma
Deep Margin: (radial) Negative for invasive carcinoma
Dysplasia at Margin: Absent
- (I) RIGHT NECK DISSECTION, LEVEL IV:
Thirteen lymph nodes, no tumor present (0/13).

[page 2 of 3]
(J) TEETH.

Gross examination only.

Entire report and diagnosis completed by [REDACTED]

GROSS DESCRIPTION

(A) LEFT NECK, LEVEL I - Received is a fragment of fatty tissue with attached submandibular gland. Fatty tissue measures 8.0 x 4.0 x 1.0 cm. Submandibular gland measures 3.0 x 2.0 cm. Dissection reveals 12 possible lymph nodes ranging from 0.3 x up to 2.5 cm in greatest dimension. Grossly the largest lymph node is positive for malignancy. Cut surface of the submandibular gland is unremarkable.

SECTION CODE: A1, five possible lymph nodes; A2, three possible lymph nodes; A3, one sectioned lymph node; A4, one sectioned lymph node; A5, one sectioned lymph node; A6, representative sections of the grossly positive for malignancy lymph node; A7, representative sections of submandibular gland (the rest of the grossly positive for malignancy lymph node is submitted to tumor bank). [REDACTED]

(B) LEFT NECK DISSECTION, LEVEL II - Received is a single fragment of fatty tissue measuring 3.5 x 2.8 x 0.8 cm. Dissection reveals fourteen possible lymph nodes ranging from 0.3 up to 1.8 cm in greatest dimension. Nodes are entirely submitted.

SECTION CODE: B1, six possible lymph nodes; B2, four possible lymph nodes; B3, one sectioned possible lymph node; B4, one sectioned possible lymph node; B5, one sectioned possible lymph node; B6, one sectioned possible lymph node. [REDACTED]

(C) LEFT NECK DISSECTION, LEVEL III - Received is a single fragment of fatty tissue measuring 4.5 x 1.5 cm. Dissection reveals 14 possible lymph nodes ranging from 0.2 up to 2.0 cm in greatest dimension. Nodes are entirely submitted.

SECTION CODE: C1, three possible lymph nodes; C2, four possible lymph nodes; C3, three possible lymph nodes; C4, one sectioned possible lymph node; C5, one sectioned possible lymph node; C6, one sectioned possible lymph node; C7, one sectioned possible lymph node. [REDACTED]

(D) LEFT NECK DISSECTION, LEVEL IV - Received is a single fragment of a fatty tissue measuring 3.0 x 2.0 cm. Dissection reveals 22 possible lymph nodes ranging from 0.2 up to 1.0 cm in greatest dimension. Nodes are entirely submitted.

SECTION CODE: D1, six possible lymph nodes; D2, five possible lymph nodes; D3, five possible lymph nodes; D4, three possible lymph nodes; D5, one sectioned possible lymph node; D6, one sectioned possible lymph node; D7, one sectioned possible lymph node. [REDACTED]

(E) RIGHT NECK DISSECTION, LEVEL I - A segment of salivary gland (probably submandibular) measuring 3.5 x 2.0 x 1.0 cm, with 5cm adjacent adipose tissue. Dissection of adipose tissue reveals three possible lymph nodes ranging in size from 0.5 to 1.5 cm. Cross sections of the submandibular salivary gland are unremarkable.

SECTION CODE: E1, two possible lymph nodes; E2, one possible lymph node bisected; E3, representative sections of unremarkable salivary gland. [REDACTED]

(F) RIGHT NECK DISSECTION, LEVEL II - A 5.0 x 3.5 x 1.0 cm fibromuscular adipose tissue fragment is dissected revealing fifteen possible lymph nodes ranging from 0.1 to 1.7 cm in greatest dimension. A 2.0 x 1.5 x 0.5 cm portion of probable grossly unremarkable glandular tissue is identified.

SECTION CODE: F1, one possible lymph node serially sectioned; F2, one possible lymph node serially sectioned; F3, one possible lymph node serially sectioned; F4, one possible lymph node bisected; F5, four possible lymph nodes entirely

[page 3 of 3]
submitted; F6, two possible lymph nodes entirely submitted; F7, four possible lymph nodes entirely submitted; F8, glandular tissue, entirely submitted; F9, muscular tissue representative. [REDACTED]

(G) RIGHT NECK DISSECTION, LEVEL III - A 4.0 x 2.5 x 0.8 cm fibromuscular and adipose tissue fragment is dissected revealing fifteen possible lymph nodes ranging from 0.1 to 1.5 cm in greatest dimension.

SECTION CODE: G1, one possible lymph node serially sectioned; G2, one possible lymph node trisected; G3, one possible lymph node bisected; G4, one possible lymph node bisected; G5, four possible lymph nodes entirely submitted; G6, five possible lymph nodes entirely submitted; G7, four possible lymph nodes entirely submitted; G8, muscular tissue representative. [REDACTED]

(H) PARTIAL GLOSSECTOMY (STITCH RIGHT FLOOR OF MOUTH) - A partial glossectomy (overall 6.5 x 4.0 x 2.0 cm). There is a stitch that designates the right floor of mouth. There is an ulcerated mass (4.5 x 2.8 x 2.2 cm) extending from the left lateral tongue inferiorly spanning the dorsal surface of the tongue to the right floor of mouth. This mass is 2.0 cm from the posterior resection margin (comprised of skeletal muscle) and 1.5 cm from the posterior dorsal margin. The entire margin is shaved off circumferentially (dorsal, floor of mouth and skeletal muscle). Representative sections are submitted. The tongue is sliced from anterior to posterior to reveal that the mass has focal areas of invasion. Representative sections are submitted sequentially from anterior to posterior.

SECTION CODE: H1, anterior floor of mouth margin, en face; H2, posterior floor of mouth margin, en face; H3-H7, entire dorsal posterior margin, en face H3, posterior margin, floor of mouth; H9, muscle margin; H10-H17, sections of tumor and tongue sequentially submitted from anterior to posterior, representative sections (possible invasion in section A13. Please correlate microscopically). [REDACTED]

*FS/DX: NO TUMOR PRESENT [REDACTED]

(I) RIGHT NECK DISSECTION, LEVEL IV - A 3.0 x 1.3 x 1.3 cm fibroadipose tissue reveals twelve possible lymph nodes ranging from 0.1 to 1.5 cm in greatest dimension.

SECTION CODE: I1, one possible lymph node trisected; I2, five possible lymph nodes, entirely submitted; I3, four possible lymph nodes entirely submitted; I4, two possible lymph nodes entirely submitted [REDACTED]

(J) TEETH - Multiple teeth aggregating to 6.0 x 5.0 x 1.0 cm. Gross examination only. [REDACTED]

CLINICAL HISTORY

Squamous cell carcinoma of tongue. [REDACTED]

SNOMED CODES

M-80703, M-43000, T-53000, T-C4000, M-80706

"Some tests reported here may have been developed and performance characteristics determined by [REDACTED] Pathology and Laboratory Medicine. These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Released by: [REDACTED]

Source: NCI Genomic Data Commons file 075aae95-ec17-4af7-86ca-4c2cf90fa485 (TCGA-CV-5977.7808AD31-A68D-4EFE-81B0-8D4122DFF998.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).